Gene-level copy-number profile of tumor specimen TCGA-62-A46Y-01A from TCGA case TCGA-62-A46Y, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.9 years (25,905 days).
Specimen TCGA-62-A46Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.058a3f72-41b3-450a-8a8e-df122d532517.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-62-A46Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6fe650e6-605e-4d67-9df3-80d3d33e86b7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,061; copy number 2: 50,855; copy number 3: 3,373; copy number 4: 491; copy number 5: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-62-A46Y-01A-11D-A24C-01): tumor purity 0.48, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 40 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:23,529,504–24,562,544, 1 gene, copy number 5 (within-gene range 4–5): SOX5.
- chr12:24,212,421–25,409,445, 25 genes, copy number 5: MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1.
- chr12:25,423,600–25,441,052, 3 genes, copy number 5: AC092451.2, FAM133GP, TUBB4BP1.
- chr12:29,149,103–29,340,980, 1 gene, copy number 5 (within-gene range 4–5): FAR2.
- chr12:29,277,397–29,784,759, 10 genes, copy number 5 (within-gene range 2–5): AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1, TMTC1, AC009320.1, RPL21P99.

Autosomal genes at a single copy (total copy number 1): 5,061. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
